TCGA case TCGA-02-0336 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center.
https://portal.gdc.cancer.gov/cases/aac1baa7-71ca-430f-b008-e5f20b412961

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-02-0336-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 100; Percent necrosis: 0; Percent stromal cells: 50.
  Slide TCGA-02-0336-01A-01-TS1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 100; Percent necrosis: 0; Percent stromal cells: 80.
